Gene-level copy-number profile of tumor specimen TCGA-66-2744-01A from TCGA case TCGA-66-2744, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 71.4 years (26,084 days).
Specimen TCGA-66-2744-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.cd3f79eb-4cbd-4e54-a1d9-0307e59ce20d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2744-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/58cf6902-2b91-4d5b-8cbc-a4f579b6ede0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 4,420; copy number 2: 35,368; copy number 3: 15,180; copy number 4: 2,057; copy number 5: 294; copy number 6: 1,331; copy number 7: 197; copy number 8: 415; copy number 9: 91; copy number 11: 73; copy number 12: 230; copy number 13: 39; copy number 15: 9; copy number 16: 11; copy number 17: 29; copy number 18: 1; copy number 21: 8; copy number 24: 27; copy number 27: 9; copy number 36: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2744-01A-01D-1969-01): tumor purity 0.37, ploidy 2.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,373,353–3,700,628, 3 genes: AC026991.1, AC026991.2, RNA5SP251.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,775 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:79,025,686–86,213,790, 110 genes, copy number 8 (broad region; genes not listed).
- chr2:142,131,178–143,055,833, 5 genes, copy number 5: AC078882.1, UBE2V1P14, RRN3P4, KYNU, SFXN4P1.
- chr2:143,093,056–143,172,172, 10 genes, copy number 5: MTCYBP11, MTND6P11, MTND5P24, MTND4P22, MTND4LP12, MTND3P9, MTCO3P5, MTATP6P5, MTCO2P5, AC013437.1.
- chr4:31,997,376–57,110,385, 353 genes, copy number 6–7 (broad region; genes not listed).
- chr4:57,110,547–57,111,400, 1 gene, copy number 7: AC111197.1.
- chr5:58,198–34,373,850, 525 genes, copy number 6–15 (broad region; genes not listed).
- chr5:36,861,736–45,895,970, 146 genes, copy number 6–18 (broad region; genes not listed).
- chr6:57,961,438–58,438,364, 1 gene, copy number 5 (within-gene range 3–5): AL445250.1.
- chr6:58,071,720–63,779,336, 33 genes, copy number 5: AL390237.1, RBBP4P4, AL603755.1, AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 5: AL354719.1, SCAT8, GCNT1P4.
- chr7:82,754,012–92,971,299, 112 genes, copy number 7–9 (broad region; genes not listed).
- chr8:125,648,327–138,083,657, 146 genes, copy number 6–21 (within-gene range 3–21) (broad region; genes not listed).
- chr9:1,151,807–7,961,224, 113 genes, copy number 6–12 (broad region; genes not listed).
- chr9:13,274,510–15,544,294, 38 genes, copy number 6–9: AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P.
- chr9:15,588,355–15,588,615, 1 gene, copy number 6: HMGN2P16.
- chr10:42,747,544–46,391,784, 103 genes, copy number 5 (broad region; genes not listed).
- chr10:46,398,362–46,453,306, 2 genes, copy number 5 (within-gene range 2–5): LINC00842, HNRNPA1P33.
- chr10:50,990,888–52,298,423, 1 gene, copy number 5 (within-gene range 2–5): PRKG1.
- chr10:51,695,486–51,699,595, 1 gene, copy number 5: CSTF2T.
- chr11:10,272,052–17,389,331, 122 genes, copy number 8–16 (broad region; genes not listed).
- chr11:68,460,731–68,615,334, 1 gene, copy number 13 (within-gene range 3–13): PPP6R3.
- chr11:68,612,899–71,670,297, 85 genes, copy number 13–36 (broad region; genes not listed).
- chr11:72,562,044–80,762,826, 211 genes, copy number 12 (broad region; genes not listed).
- chr13:18,467,172–20,091,829, 58 genes, copy number 7 (within-gene range 3–7): ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1, AL137001.2, RNA5SP24, CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1, PSPC1P1, ANKRD26P3, MRPL3P1, LINC00421, PARP4P2, CCNQP3, AL356259.1, SLC25A15P2, TPTE2, CYCSP32, MRPS31P2, ESRRAP1, LINC00350, CASC4P1, MPHOSPH8, PSPC1-AS2, PSPC1, RN7SL166P, ST6GALNAC4P1, ZMYM5, AL355001.1, AL355001.2, ZMYM2.
- chr13:34,545,929–41,961,120, 111 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr13:57,391,171–60,573,878, 24 genes, copy number 5 (within-gene range 3–5): RPL31P53, PCDH17, AL445288.1, RNA5SP30, LINC02338, LINC00374, AL161423.1, RNY4P29, CTAGE16P, DNAJA1P1, HMGN2P39, POLR3KP1, AL159156.1, RPP40P2, RNU7-88P, DIAPH3, DIAPH3-AS1, RN7SL375P, DIAPH3-AS2, RNY4P28, LINC00434, TARDBPP2, AL359920.1, TDRD3.
- chr19:4,969,113–7,540,059, 103 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr22:20,348,758–25,564,719, 355 genes, copy number 6 (broad region; genes not listed).
- chr22:25,580,241–25,581,382, 1 gene, copy number 6: AL022329.2.

Autosomal genes at a single copy (total copy number 1): 2,246. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
